Surgical pathology report (de-identified scan), TCGA case TCGA-VR-A8ET, project TCGA-ESCA (Esophageal Carcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VR-A8ET-01A (Primary Tumor).

ICD-O-3
Carcinoma, squamous cell ^{NOT}
~~CCE~~ 8070/3
Site Esophagus, distal
thick C15.5
~~path~~ Esophagus NOS C15.9
JW 1/24/14

Collect date:
(MM/DD/YYYY)

PRIMARY SITE: Esophagus

PATHOLOGY REPORT:

1.

Specimen: Esophagus and proximal stomach

Procedure: Esophagogastrectomy

Tumor site: distal esophagus and proximal stomach

Tumor size (greatest dimension): 5.0 cm

Histologic type: Squamous cell carcinoma

Histologic grade: G2 moderately differentiated

Microscopic tumor extension: tumor invades into muscularis propria externally

Lymph-vascular invasion: not identified

Perineural invasion: present

Margins: uninvolved by carcinoma

2 - "Esophageal margin":

Uninvolved by carcinoma.

3. "Regional lymph nodes":

Number examined: 17 (right paracardics 0/1; left paracardics 0/10; lesser curvature of stomach 0/1; celiac trunk 0/3; lower esophagus 0/2)

Number positive for neoplasia: 00

Significant Discrepancy		☒
Primary Discrepancy		☒
Qual/Sync. Tumorous Form: y noted		☒

Source: NCI Genomic Data Commons file 4e9b6534-dae7-4196-884f-fce3a5a02375 (TCGA-VR-A8ET.BD6C26A1-DF17-41C1-979F-4507FCD866E5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).